Surgical pathology report (de-identified scan), TCGA case TCGA-OY-A56Q, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of North Carolina, specimen TCGA-OY-A56Q-01A (Primary Tumor).

[page 1 of 5]
ICD-0-3

Carcinoma, Serous NOS
844113

Site: Path "Favors Ovary"

CSCF Ovary

12/4/12

C56.9

Diagnosis:

-A: Ovary and fallopian tube, left, left salpingo-oophorectomy

Histologic type: serous carcinoma

Histologic grade: poorly differentiated

Tumor size: 8 x 8 x 7 cm per gross measurement

Ovarian surface involvement: not identified

Status of capsule: intact

Extent of involvement of other tissues/organs:

Left fallopian tube Hydrosalpinx and positive for serous carcinoma, predominantly detached within the lumen and focally involving mucosa (see comment).

Regional lymph nodes (see other specimens):

Total number involved: 0

Total number examined: 14

AJCC Pathologic Stage: pT1a pN0 pMx (see comment)

Note: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

[page 2 of 5]
Other findings:

- Fibrous serosal adhesions

B: Fallopian tube and ovary, right, salpingo-oophorectomy

- Atrophic ovary with epithelial inclusion glands and cysts
- Fallopian tube with paratubal cysts
- Tubo-ovarian adhesions
- No malignancy identified

C: Omentum, partial omentectomy

- Omentum with no malignancy identified

D: Lymph nodes, left common iliac, regional resection

- Four lymph nodes negative for metastatic carcinoma (0/4)

E: Lymph nodes, left periaortic, regional resection

- Four lymph nodes negative for metastatic carcinoma (0/4)

F: Lymph nodes, left pelvic, regional resection

- Six lymph nodes negative for metastatic carcinoma (0/6)

Comment:

The majority of the serous carcinoma is present in the ovary in specimen A.

Representative section of right fallopian tube shows predominantly intraluminal

serous carcinoma with focal attachment and involvement of mucosa. No

parenchymal invasive carcinoma is identified in the right fallopian tube. Based

on the majority of the tumor present in ovary and predominantly luminal tumor

within the fallopian tube without significant mucosal in situ carcinoma or

parenchymal invasion identified in the fallopian tube, ovarian origin of the

serous carcinoma is favored. The scenarios include primary ovary serous

carcinoma with secondary involvement of fallopian tube, primary fallopian tube

carcinoma with secondary involvement of ovary and two synchronous primaries. An

ovarian primary is favored as discussed above, although an origin in the

fallopian tube cannot be entirely excluded by pathologic examination.

[page 3 of 5]
Note, no peritoneal washings are received. The pathologic stage is based on examination of the surgical specimens only.

Intraoperative Consult Diagnosis:

A frozen section consultation was requested by

FSA1: Ovary and tube, left, left salpingo-oophorectomy
- High grade carcinoma, favor serous

Frozen Section Pathologist:, MD

Clinical History:

year-old female with an adnexal mass.

Gross Description:

Received are six appropriately labeled containers. Specimen A is received fresh for frozen section.

Container A is additionally labeled "left tube and ovary."

Specimen fixation: formalin

Type of specimen: salpingo-oophorectomy

Tumor site: left

Ovary/tumor size: 215 grams, 8.0 x 8.0 x 7.0 cm, which is received intact

Ovarian surface: pink/tan, smooth and glistening with diffuse fibrofatty adhesions and excrescences absent

Description of tumor: The specimen consists of a unilocular cyst that is filled with brown serous fluid and loosely adherent clumps of brown material; there are two foci of tan friable papillary excrescences up to 2.1 x 1.7 x 1.5 cm in greatest dimension.

[page 4 of 5]
The wall ranges from 0.1 cm thick up to 0.4 cm thick. Normal ovarian parenchyma is absent.

Fallopian tube: present, without fimbria and is embedded within the wall,
4.2 cm long x 0.6 cm in diameter; the wall is 0.2 cm thick; the lumen is patent and the mucosa is tan and friable; the lumen is partially filled with adherent yellow/tan gelatinous material

Digital Picture: not taken

Tissue submitted for Special Investigation: no

Block summary:

FSA1 - frozen section remnant
A2-A7 - ovarian cyst with excrescences, blocks A2-A4; external surface is inked black in A4
A8-A9 - fallopian tube

Container B is additionally labeled "right adnexa." It consists of a 4.7 x 3.7 x 2.6 cm portion of adipose tissue that encases a 3.4 x 1.5 x 1.5 cm ovary and a 3.2 cm long x 0.5 cm in diameter fimbriated fallopian tube. The ovary has a 0.8 x 0.7 x 0.7 cm intraparenchymal empty simple cyst that is lined by smooth and glistening wall without excrescences. The wall is less than 0.1 cm thick. The fallopian tube has a pinpoint lumen with a tan mucosa.

Block summary:

B1-B4 - ovary and fallopian tube with longitudinal fimbria in B2 and ovarian cyst in B3

Container C is additionally labeled "omentum." It consists of a 9.1 x 6.2 x 1.3

[page 5 of 5]
cm unremarkable segment of omentum that is represented in block C1.

Container D is additionally labeled "left common iliac nodes."
It consists of a
2.5 x 1.0 x 0.6 cm portion of adipose tissue that contains four
lymph node
candidates ranging from 0.5 x 0.4 x 0.3 cm up to 1.5 x 0.6 x 0.4
cm in greatest
dimension.

Block summary:

D1 - four lymph node candidates
D2 - remainder of specimen for potential lymph node candidates,

Container E is additionally labeled "left periaortic node." It
consists of a 1.7
x 1.3 x 1.0 cm portion of adipose tissue that contains two lymph
node candidates
(1.2 x 0.4 x 0.4 cm and 1.2 x 0.5 x 0.4 cm). (Block E1,

Container F is additionally labeled "left pelvic nodes." It
consists of a 4.3 x
3.1 x 1.8 cm aggregate of adipose tissue that is bisected for
lymph node
candidates. Six lymph node candidates are identified ranging
from 0.4 cm in
greatest dimension up to 3.9 x 1.5 x 1.2 cm in greatest
dimension.

Block Summary:

F1 - two lymph nodes
F2,F3,F4 each contains one lymph node candidate, serially
sectioned
F5-F7 - one lymph node candidate, serially sectioned
F8,F9 - remainder of adipose tissue for potential lymph node
candidates,

Reviewed In	11/26/12	2/24/12

Source: NCI Genomic Data Commons file 00ec5968-c122-421e-8b66-4349345134de (TCGA-OY-A56Q.3EF6F66B-8B6E-48E6-9CF4-F8A6B236856D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).